Gene-level copy-number profile of tumor specimen C3L-10122-05 from CPTAC case C3L-10122, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 72.8 years (26,594 days).
Specimen C3L-10122-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3d4802e2-7ac3-483f-9190-464a41ca44a4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-10122-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/2be939a9-6275-4528-ab5c-b67fa4d11580

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 374; copy number 2: 22,456; copy number 3: 21,599; copy number 4: 10,736; copy number 5: 2,119; copy number 6: 778; copy number 7: 184; copy number 8: 6; copy number 9: 25; copy number 11: 16; copy number 12: 1; copy number 14: 15; copy number 38: 11; copy number 39: 1; copy number 40: 10; copy number 42: 16; copy number 44: 2; copy number 45: 1; copy number 46: 2; copy number 47: 6; copy number 67: 14; copy number 74: 3; copy number 77: 6; copy number 79: 4; copy number 85: 5; copy number 86: 2; copy number 92: 5; copy number 110: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,233 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–64,116, 1 gene, copy number 12: OR4G11P.
- chr2:134,735,464–134,918,710, 5 genes, copy number 5 (within-gene range 3–5): CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590.
- chr3:128,619,969–128,681,075, 3 genes, copy number 5: RPN1, Metazoa_SRP, POU5F1P6.
- chr5:133,913,677–134,151,865, 6 genes, copy number 6 (within-gene range 3–6): WSPAR, C5orf15, VDAC1, AC008608.2, AC008608.1, TCF7.
- chr6:104,864,464–105,083,332, 3 genes, copy number 40–86: LIN28B-AS1, LIN28B, RNU6-1106P.
- chr6:105,273,218–107,459,564, 34 genes, copy number 5–110: PREP, AL133406.2, AL133406.1, RPL35P3, LINC02836, Z97206.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr6:107,702,154–107,986,031, 8 genes, copy number 5–45: SCML4, SEC63, RNU6-437P, RPL23AP50, AL024507.2, AL024507.1, SNORA73, MTHFD2P3.
- chr7:55,764,797–55,773,288, 1 gene, copy number 11: PSPHP1.
- chr7:63,556,598–63,636,617, 4 genes, copy number 8: SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1.
- chr7:72,829,425–77,783,022, 168 genes, copy number 5 (broad region; genes not listed).
- chr7:112,953,282–118,496,171, 78 genes, copy number 5 (broad region; genes not listed).
- chr8:59,119,040–59,137,502, 2 genes, copy number 44 (within-gene range 3–44): AC090152.1, AC087698.1.
- chr8:69,424,849–70,506,818, 26 genes, copy number 38–42: LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1.
- chr8:106,980,967–106,981,571, 1 gene, copy number 40: AP003789.1.
- chr10:14,959,388–15,021,863, 5 genes, copy number 5: MEIG1, OR7E110P, OR7E26P, OR7E115P, DCLRE1CP1.
- chr10:42,149,310–42,367,974, 6 genes, copy number 5: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1.
- chr10:97,153,045–97,446,017, 15 genes, copy number 6 (within-gene range 4–6): ARHGAP19-SLIT1, AL512424.1, ARHGAP19, AL359385.1, Metazoa_SRP, RPL12P27, FRAT1, FRAT2, AL355490.1, RRP12, RPL34P20, AL355490.2, Y_RNA, PGAM1, EXOSC1.
- chr11:34,430,880–34,743,199, 8 genes, copy number 5: CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1.
- chr11:66,590,176–76,216,025, 357 genes, copy number 6–7 (broad region; genes not listed).
- chr11:85,852,557–85,854,943, 1 gene, copy number 8: AP000974.1.
- chr11:97,222,644–97,259,987, 1 gene, copy number 5: LINC02553.
- chr12:56,923,133–56,959,374, 3 genes, copy number 74: SDR9C7, AC026120.2, RDH16.
- chr12:57,128,483–57,213,361, 3 genes, copy number 6 (within-gene range 3–6): LRP1, LRP1-AS, MIR1228.
- chr12:57,431,116–57,472,268, 5 genes, copy number 85 (within-gene range 3–85): AC126614.1, INHBC, INHBE, AC022506.2, GLI1.
- chr12:57,747,727–57,756,013, 1 gene, copy number 79 (within-gene range 3–79): CDK4.
- chr12:57,755,103–57,772,119, 3 genes, copy number 79 (within-gene range 3–79): MARCHF9, CYP27B1, METTL1.
- chr12:57,819,927–57,846,729, 1 gene, copy number 67 (within-gene range 3–67): CTDSP2.
- chr12:57,837,092–58,395,138, 13 genes, copy number 67: AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr14:34,556,226–34,561,298, 2 genes, copy number 5 (within-gene range 2–5): RNU1-28P, AL445363.2.
- chr16:14,953,012–15,139,339, 7 genes, copy number 6 (within-gene range 3–6): AC138932.3, PDXDC1, AC138932.2, MIR1972-1, AC138932.4, NTAN1, RRN3.
- chr16:21,376,648–21,550,373, 10 genes, copy number 5: SNX29P1, AC008740.2, NPIPB3, SMG1P3, MIR3680-1, AC005632.6, SLC7A5P2, AC005632.5, AC005632.2, AC005632.4.
- chr16:46,469,341–46,575,094, 4 genes, copy number 7: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1.
- chr16:70,173,322–70,660,682, 21 genes, copy number 5: CLEC18C, AC009060.2, SMG1P7, EXOSC6, AARS1, RN7SL279P, DDX19B, AC012184.2, AC012184.3, DDX19A, AC012184.4, ST3GAL2, AC012184.1, RPS27P26, RNU6-23P, FCSK, COG4, SF3B3, SNORD111B, SNORD111, IL34.
- chr17:27,798,806–32,143,135, 239 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr17:38,936,432–42,578,366, 219 genes, copy number 6–14 (broad region; genes not listed).
- chr17:49,085,511–51,521,401, 111 genes, copy number 5 (broad region; genes not listed).
- chr19:43,460,787–48,868,617, 285 genes, copy number 5 (broad region; genes not listed).
- chr19:56,368,099–58,605,223, 164 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:87,250–64,327,972, 1,401 genes, copy number 5–9 (broad region; genes not listed).
- chr21:10,612,455–13,120,807, 8 genes, copy number 5–8: SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 374. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
